Somatic mutation profile of tumor specimen TCGA-BK-A139-01A (aliquot TCGA-BK-A139-01A-11D-A272-09) from TCGA case TCGA-BK-A139, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 74.1 years (27,077 days).
Specimen TCGA-BK-A139-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 27443990-1d5b-44b1-aded-d5d2f021dbb1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BK-A139-10A (Blood Derived Normal), aliquot TCGA-BK-A139-10A-01D-A272-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e6e100f0-627e-4bc4-880f-9ab1078aa5fb

The open-access MAF lists 133 somatic variants for this specimen: 98 protein-altering or splice-affecting, 29 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 88, Silent 29, Nonsense Mutation 4, 5'UTR 2, Splice Region 2, RNA 2, Splice Site 1, Intron 1, Nonstop Mutation 1, Frame Shift Del 1, In Frame Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1717_1722del p.L573_R574del (on ENST00000521381 / NM_181523.3; = p.L303_R304del on NM_181504.4) | In Frame Del (DEL) | VAF 41/102 reads (40%) | hotspot (GDC flag); catalogued as COSV57129439; called by mutect2, pindel, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 37/82 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAM22 | c.2128G>C p.D710H | Missense Mutation (SNP) | VAF 13/173 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99716360; called by muse, mutect2
- ANK3 | c.8476T>A p.S2826T | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as COSV99779249; called by muse, mutect2
- ANKRD17 | c.4488A>T p.R1496S | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.173); catalogued as COSV100428552; called by muse, mutect2
- ANKRD17 | c.4487G>T p.R1496I | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.503); catalogued as COSV100428554; called by muse, mutect2
- ARFGEF2 | c.3900C>G p.Y1300* | Nonsense Mutation (SNP) | VAF 9/129 reads (7%) | catalogued as COSV100904175; called by muse, mutect2
- ASGR2 | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 63/148 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs775565123, COSV54690086; called by muse, mutect2, varscan2
- ASH2L | c.1849G>A p.E617K | Missense Mutation (SNP) | VAF 89/190 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.152); catalogued as COSV51698421; called by muse, mutect2, varscan2
- AXDND1 | c.2294G>T p.C765F | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.547); catalogued as rs1328041323, COSV62642011; called by muse, varscan2
- BCL7A | c.233C>G p.P78R | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99946903; called by muse, mutect2
- BSN | c.4183C>T p.R1395* | Nonsense Mutation (SNP) | VAF 17/119 reads (14%) | catalogued as COSV99607231; called by muse, mutect2, varscan2
- CAMKV | c.637C>T p.L213= | Splice Region (SNP) | VAF 22/74 reads (30%) | catalogued as rs200019805, COSV56555122; called by muse, mutect2, varscan2
- CAPRIN1 | c.1760A>G p.H587R | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.992); catalogued as rs759068488, COSV58219562; called by muse, mutect2, varscan2
- CBX6 | c.1085T>A p.M362K | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53320749; called by muse, mutect2, varscan2
- CCDC82 | c.1121T>C p.L374P | Missense Mutation (SNP) | VAF 63/178 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1182611261, COSV53593198; called by muse, mutect2, varscan2
- CDADC1 | c.832G>A p.D278N | Missense Mutation (SNP) | VAF 13/138 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV51911319; called by muse, mutect2
- CDH7 | c.1087A>T p.T363S | Missense Mutation (SNP) | VAF 25/191 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV59885250; called by muse, mutect2, varscan2
- COL9A2 | c.1952G>A p.R651Q | Missense Mutation (SNP) | VAF 32/200 reads (16%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.912); catalogued as rs199850925, COSV65622693; called by muse, mutect2, varscan2
- CPNE8 | c.1437G>A p.M479I | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs1404165216, COSV58842313, COSV58848917; called by muse, mutect2, varscan2
- CSN2 | c.681A>C p.*227Yext*14 | Nonstop Mutation (SNP) | VAF 19/232 reads (8%) | catalogued as COSV100778720; called by muse, mutect2
- DMXL2 | c.3188G>C p.S1063T | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV51845230; called by muse, mutect2, varscan2
- DNAJC1 | c.513G>T p.W171C | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100977997; called by muse, mutect2
- DOCK7 | c.4833T>A p.F1611L (on ENST00000635253 / NM_001367561.1; = p.F1580L on NM_033407.3) | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.561); catalogued as COSV52003612; called by muse, mutect2, varscan2
- DYNLRB1 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as rs573896721, COSV64063820; called by muse, varscan2
- ELF5 | c.212A>T p.E71V (on ENST00000312319 / NM_198381.2; = p.E61V on NM_001422.4) | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56628736; called by muse, mutect2, varscan2
- EVC2 | c.231C>A p.D77E | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.014); catalogued as rs776531365, COSV60388298; called by muse, mutect2, varscan2
- FAM151B | c.379C>T p.P127S | Missense Mutation (SNP) | VAF 82/136 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV56472878; called by muse, mutect2, varscan2
- FAT1 | c.6488C>A p.A2163D | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV71673152, COSV71673571; called by muse, mutect2, varscan2
- FAT3 | c.4670A>G p.E1557G | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV99961793; called by muse, mutect2, varscan2
- FETUB | c.697C>T p.P233S | Missense Mutation (SNP) | VAF 28/237 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54005465; called by muse, mutect2, varscan2
- FOXF2 | c.1327G>A p.V443I | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs181428616, COSV52525311; called by muse, mutect2, varscan2
- FOXR1 | c.740G>A p.R247Q | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.081); catalogued as rs150635174, COSV57652017; called by muse, mutect2, varscan2
- GFI1 | c.212C>T p.S71F | Missense Mutation (SNP) | VAF 24/279 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs763578383, COSV99647478; called by muse, mutect2
- GLI3 | c.4628C>G p.A1543G | Missense Mutation (SNP) | VAF 20/181 reads (11%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.701); catalogued as COSV67887890, COSV67895815; called by muse, mutect2, varscan2
- GSAP | c.2294G>T p.R765I | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as rs1201603617, COSV57529582; called by muse, mutect2, varscan2
- GSDME | c.55C>A p.L19M | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV61651528; called by muse, mutect2, varscan2
- H3-3A | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.006); catalogued as COSV64732596; called by muse, mutect2, varscan2
- HELT | c.589C>T p.P197S | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV58819880; called by muse, mutect2
- HLA-DQA2 | c.35T>G p.L12R | Missense Mutation (SNP) | VAF 16/296 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.782); catalogued as COSV100890695; called by muse, mutect2
- IVL | c.1346A>G p.Q449R | Missense Mutation (SNP) | VAF 31/253 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV100908140; called by muse, mutect2, varscan2
- KCNH8 | c.1806C>G p.S602R | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.752); catalogued as COSV100109272; called by muse, mutect2
- KCNN1 | c.1180G>A p.A394T | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.229); catalogued as rs1260374056, COSV55838552; called by muse, mutect2, varscan2
- KCTD17 | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 55/128 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63248902; called by muse, mutect2, varscan2
- KDM3B | c.1376G>A p.G459E | Missense Mutation (SNP) | VAF 53/109 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as rs1561770083, COSV58690112; called by muse, mutect2, varscan2
- KIT | c.794G>A p.G265D | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.984); catalogued as COSV55395364; called by muse, mutect2
- LACTB | c.1388C>T p.A463V | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1314145412, COSV56055541; called by muse, mutect2, varscan2
- LCE2B | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 62/144 reads (43%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as rs767189385, COSV64227613; called by muse, mutect2, varscan2
- LGI4 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs144343503, COSV100032601; called by muse, mutect2, varscan2
- LONP2 | c.1464A>G p.I488M | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV53522139; called by muse, mutect2, varscan2
- MKNK2 | c.1102G>A p.V368I | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.491); catalogued as COSV51732110; called by muse, mutect2, varscan2
- MTMR10 | c.931C>T p.Q311* | Nonsense Mutation (SNP) | VAF 13/61 reads (21%) | catalogued as COSV58727977; called by muse, mutect2, varscan2
- MTMR8 | c.1175C>G p.S392C | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as COSV66393605; called by muse, mutect2, varscan2
- MUC17 | c.6913G>T p.D2305Y | Missense Mutation (SNP) | VAF 142/295 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.262); catalogued as COSV60287027; called by muse, mutect2, varscan2
- MYO1H | c.2080C>T p.R694C | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764150151, COSV60443340; called by muse, mutect2, varscan2
- NCOA3 | c.2231G>C p.R744T | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as COSV100507373; called by muse, mutect2
- NOG | c.610C>T p.R204W | Missense Mutation (SNP) | VAF 9/146 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100240543; called by muse, mutect2
- NOTCH4 | c.4031G>A p.G1344E | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100900570; called by muse, mutect2, varscan2
- NRG1 | c.1451C>A p.P484Q (on ENST00000405005 / NM_013964.5; = p.P489Q on NM_013956.5) | Missense Mutation (SNP) | VAF 43/86 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV55157105; called by muse, mutect2, varscan2
- OCIAD1 | c.244G>C p.A82P | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51900609; called by muse, mutect2, varscan2
- OR2B11 | c.51C>G p.I17M | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.146); catalogued as COSV59510030; called by muse, mutect2, varscan2
- OR51E2 | c.490C>T p.R164W | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as rs151286283; called by muse, mutect2, varscan2
- OR8K1 | c.715G>T p.G239W | Missense Mutation (SNP) | VAF 53/139 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV54402287, COSV54403778; called by muse, mutect2, varscan2
- OSMR | c.140G>T p.S47I | Missense Mutation (SNP) | VAF 56/283 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.05); catalogued as COSV57084303; called by muse, varscan2
- PCLO | c.9754A>G p.M3252V | Missense Mutation (SNP) | VAF 11/152 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as rs1181678596, COSV100430120; called by muse, mutect2
- PCNX4 | c.2882T>C p.I961T (on ENST00000406854 / NM_001330177.2; = p.I727T on NM_022495.5) | Missense Mutation (SNP) | VAF 59/164 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as COSV58303752; called by muse, mutect2, varscan2
- PDGFB | c.571C>T p.R191* | Nonsense Mutation (SNP) | VAF 15/187 reads (8%) | catalogued as rs761574566, COSV100483421; called by muse, mutect2
- PLXND1 | c.4412T>C p.I1471T | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs1389101617, COSV100139403; called by muse, mutect2
- PRDM14 | c.631C>A p.P211T | Missense Mutation (SNP) | VAF 59/217 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.018); catalogued as COSV52571980; called by muse, mutect2, varscan2
- PRPF19 | c.632C>A p.A211E | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV57128507, COSV99920449; called by muse, mutect2, varscan2
- PSME4 | c.4705C>A p.Q1569K | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT tolerated (0.62); PolyPhen benign (0.011); catalogued as COSV66363135, COSV66364667; called by muse, mutect2
- PSME4 | c.4222C>A p.L1408M | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV101122402; called by muse, mutect2
- PTCH1 | c.3070C>A p.L1024I | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100107462; called by muse, mutect2, varscan2
- PTPRN2 | c.318C>A p.D106E | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV101233607; called by muse, mutect2
- SIGLEC8 | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 79/219 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.228); catalogued as rs746803267, COSV100367206, COSV58471655; called by muse, mutect2, varscan2
- SLC20A2 | c.1133G>A p.R378Q | Missense Mutation (SNP) | VAF 37/215 reads (17%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.49); catalogued as rs1055093172, COSV60603252, COSV60607612; called by muse, mutect2, varscan2
- SLC44A5 | c.1624+2T>A p.X542_splice | Splice Site (SNP) | VAF 9/81 reads (11%) | catalogued as COSV63763600; called by muse, mutect2, varscan2
- SMR3A | c.45del p.C16Vfs*106 | Frame Shift Del (DEL) | VAF 44/237 reads (19%) | catalogued as COSV56949617, COSV56950143; called by mutect2, pindel, varscan2
- SPIN3 | c.389G>T p.G130V | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100888463; called by muse, mutect2, varscan2
- TECTA | c.1114G>T p.G372C | Missense Mutation (SNP) | VAF 40/140 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.961); catalogued as COSV50703368; called by muse, mutect2, varscan2
- TENM3 | c.489A>C p.E163D | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.01); catalogued as COSV69306268; called by muse, mutect2, varscan2
- TLL1 | c.319G>T p.A107S | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV50275636, COSV50308643; called by muse, mutect2, varscan2
- TMC7 | c.652G>T p.V218L | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV58583118; called by muse, mutect2, varscan2
- TMEM204 | c.11A>C p.Q4P | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.244); catalogued as COSV99559685; called by muse, mutect2, varscan2
- TMEM47 | c.356T>A p.L119H | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99327464; called by muse, varscan2
- TNIK | c.3380C>A p.P1127Q | Missense Mutation (SNP) | VAF 8/241 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99456308; called by muse, mutect2
- TRIM67 | c.1303C>T p.R435C | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs372382212, COSV64158042; called by muse, mutect2, varscan2
- TRIM69 | c.834T>C p.H278= (on ENST00000329464 / NM_182985.5; = p.H119= on NM_080745.5) | Splice Region (SNP) | VAF 49/144 reads (34%) | catalogued as rs1264818442, COSV57803580; called by muse, mutect2, varscan2
- TTC17 | c.190C>G p.H64D | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.942); catalogued as COSV50008171; called by muse, mutect2, varscan2
- VCAN | c.1837G>A p.D613N | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.15); catalogued as COSV54103886; called by muse, mutect2, varscan2
- XIRP2 | c.7142A>C p.E2381A (on ENST00000628543; = p.E2556A on NM_152381.6) | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV54696516; called by muse, mutect2, varscan2
- ZBTB24 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as rs761960881, COSV57781908; called by muse, mutect2, varscan2
- ZC3H6 | c.2153A>C p.K718T | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.422); catalogued as COSV100674484; called by muse, mutect2
- ZNF222 | c.34G>A p.D12N | Missense Mutation (SNP) | VAF 28/390 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs756334418, COSV99496215; called by muse, mutect2
- ZNF254 | c.32G>A p.G11E | Missense Mutation (SNP) | VAF 46/219 reads (21%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.467); catalogued as COSV60054126; called by muse, mutect2, varscan2
- ZNF786 | c.1479G>T p.E493D | Missense Mutation (SNP) | VAF 55/93 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV60275865; called by muse, mutect2, varscan2
- ZNF91 | c.917C>T p.S306F | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT tolerated (0.76); PolyPhen benign (0.195); catalogued as rs1449451716, COSV100322494; called by muse, mutect2
- GLYR1 | c.725G>T p.C242F | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.246); called by muse, mutect2
- ANKRD30A | c.543G>A p.T181= (on ENST00000611781; = p.T125= on NM_052997.2) | Silent (SNP) | VAF 24/166 reads (14%) | catalogued as rs748801395, COSV64609214, COSV64609913; called by muse, mutect2, varscan2
- ARHGEF5 | c.4602C>T p.A1534= | Silent (SNP) | VAF 19/93 reads (20%) | catalogued as rs1040382186, COSV50209723; called by muse, mutect2, varscan2
- ASPM | c.234G>A p.K78= | Silent (SNP) | VAF 11/95 reads (12%) | catalogued as COSV54128917; called by muse, mutect2, varscan2
- CACNB2 | c.858A>G p.L286= (on ENST00000324631 / NM_201596.3; = p.L231= on NM_000724.4) | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as COSV56621483; called by muse, mutect2, varscan2
- COL6A1 | c.357G>A p.A119= | Silent (SNP) | VAF 16/98 reads (16%) | catalogued as rs747037863, COSV62612876, COSV62614791; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- DDX24 | c.1680G>A p.V560= | Silent (SNP) | VAF 55/131 reads (42%) | catalogued as rs767350697, COSV58212349; called by muse, mutect2, varscan2
- DHRS7C | c.840C>T p.P280= (on ENST00000330255 / NM_001220493.2; = p.P279= on NM_001105571.3) | Silent (SNP) | VAF 25/119 reads (21%) | catalogued as COSV57650551; called by muse, mutect2, varscan2
- DNM2 | c.1143G>A p.E381= | Silent (SNP) | VAF 15/106 reads (14%) | catalogued as COSV58960896; called by muse, mutect2, varscan2
- DOCK3 | c.1861C>A p.R621= | Silent (SNP) | VAF 12/157 reads (8%) | catalogued as rs369862076, COSV56544794, COSV99810601; called by muse, mutect2
- FAM47B | c.1053G>T p.L351= | Silent (SNP) | VAF 10/240 reads (4%) | catalogued as COSV100264225; called by muse, mutect2
- KPTN | c.640C>A p.R214= | Silent (SNP) | VAF 63/128 reads (49%) | catalogued as COSV57645017; called by muse, mutect2, varscan2
- LAMA2 | c.5937C>T p.N1979= | Silent (SNP) | VAF 22/103 reads (21%) | catalogued as rs747714599, COSV70345709; called by muse, mutect2, varscan2
- MBNL2 | c.765G>A p.A255= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as rs201039654; called by muse, mutect2
- MLIP | c.333C>T p.F111= | Silent (SNP) | VAF 14/95 reads (15%) | catalogued as rs201706379; called by muse, mutect2, varscan2
- PAPPA | c.3480G>A p.Q1160= | Silent (SNP) | VAF 20/74 reads (27%) | catalogued as COSV60282159; called by muse, mutect2, varscan2
- PIK3C2B | c.2958G>C p.L986= | Silent (SNP) | VAF 20/162 reads (12%) | catalogued as COSV100915978, COSV65810211, COSV65812471; called by muse, mutect2, varscan2
- PSPC1 | c.504C>T p.S168= | Silent (SNP) | VAF 35/100 reads (35%) | catalogued as COSV58887893; called by muse, mutect2, varscan2
- PTCRA | c.225C>T p.T75= | Silent (SNP) | VAF 18/184 reads (10%) | catalogued as rs1288816535, COSV100485726; called by muse, mutect2
- RETSAT | c.1722C>T p.V574= | Silent (SNP) | VAF 13/181 reads (7%) | catalogued as rs71337783, COSV99805847; called by muse, mutect2
- SAP130 | c.747G>A p.L249= | Silent (SNP) | VAF 10/104 reads (10%) | catalogued as COSV99384463; called by muse, mutect2
- SCN5A | c.1380C>T p.S460= | Silent (SNP) | VAF 36/93 reads (39%) | catalogued as COSV61122478; called by muse, mutect2, varscan2
- SIX1 | c.477G>A p.E159= | Silent (SNP) | VAF 11/111 reads (10%) | catalogued as rs1566722077, COSV99903278; called by muse, mutect2, varscan2
- SOWAHB | c.111C>G p.P37= | Silent (SNP) | VAF 34/92 reads (37%) | catalogued as COSV57554295, COSV57554402; called by muse, mutect2, varscan2
- SUZ12 | c.546T>C p.V182= | Silent (SNP) | VAF 16/89 reads (18%) | catalogued as COSV59499700; called by muse, mutect2, varscan2
- TCF3 | c.474G>C p.R158= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as rs755980732, COSV99513550; called by muse, mutect2, varscan2
- TEKT2 | c.912G>T p.L304= | Silent (SNP) | VAF 28/56 reads (50%) | catalogued as COSV52880871; called by muse, mutect2, varscan2
- TTL | c.123G>A p.L41= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV51974322; called by muse, mutect2, varscan2
- VIL1 | c.627C>T p.G209= | Silent (SNP) | VAF 28/106 reads (26%) | catalogued as rs767787005, COSV50287346; called by muse, mutect2, varscan2
- ZFC3H1 | c.1762T>C p.L588= | Silent (SNP) | VAF 25/98 reads (26%) | catalogued as COSV66432066; called by muse, mutect2, varscan2
- CACNB4 | c.148-90332T>C | Intron (SNP) | VAF 8/62 reads (13%) | catalogued as COSV99137960; called by muse, varscan2
- MTRNR2L6 | chr7:142671057 T>A | 3'Flank (SNP) | VAF 14/101 reads (14%) | called by muse, mutect2, varscan2
- SNORD115-17 | n.20T>C | RNA (SNP) | VAF 31/217 reads (14%) | called by muse, mutect2, varscan2
- SSPOP | n.5698G>A | RNA (SNP) | VAF 36/97 reads (37%) | catalogued as rs766327797, COSV50487245; called by muse, mutect2, varscan2
- TSPAN6 | c.-1C>T | 5'UTR (SNP) | VAF 14/89 reads (16%) | catalogued as COSV100885744; called by muse, mutect2, varscan2
- UCHL5 | c.-163del | 5'UTR (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
